CCDI case PBCEPG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/abb3726f-6c2c-44dd-bc6d-1c9fa4f94c74

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 19.3 years (7,041 days).

Biospecimens (3 samples)
- Sample 0DQJII: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DQJIO, 0DQJIV (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
